Somatic mutation profile of tumor specimen MP2PRT-PAUBEV-TMP1-A (aliquot MP2PRT-PAUBEV-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PAUBEV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,066 days).
Specimen MP2PRT-PAUBEV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e04364cf-8ec9-47fa-95e8-b99cdcddd305.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBEV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBEV-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2d938ad-374a-41e3-b8b6-bf6529079adb

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1S | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338777, CM940215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SGSH | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 164/466 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894641, CM012471; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP1A3 | c.1066C>T p.R356W (on ENST00000545399 / NM_001256214.2; = p.R343W on NM_152296.5) | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs782423325, COSV57488065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTAGE1 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1486039581, COSV66943137; called by muse, mutect2, varscan2
- EEF1A2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 28/674 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV53206966; called by muse, mutect2
- ERICH5 | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 106/394 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1436134198; called by muse, mutect2, varscan2
- PCDHA7 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 16/504 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); catalogued as rs781952009, COSV65342627; called by muse, mutect2
- PRKN | c.950A>G p.Q317R | Missense Mutation (SNP) | VAF 17/435 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58236783; called by muse, mutect2
- CDH20 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 184/549 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP9X | c.6719A>T p.N2240I | Missense Mutation (SNP) | VAF 19/323 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2
- WDR72 | c.1425G>A p.S475= | Silent (SNP) | VAF 106/356 reads (30%) | catalogued as rs771064286, COSV64742226; called by muse, mutect2
